Somatic mutation profile of tumor specimen TCGA-63-7021-01A (aliquot TCGA-63-7021-01A-11D-1945-08) from TCGA case TCGA-63-7021, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-7021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cf4b1c6-68e9-47f8-958c-1572a11dd9fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-7021-10A (Blood Derived Normal), aliquot TCGA-63-7021-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19d44e02-2226-4c2c-8090-2a033186d66e

The open-access MAF lists 250 somatic variants for this specimen: 195 protein-altering or splice-affecting, 50 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 50, Nonsense Mutation 12, Frame Shift Del 8, Splice Site 8, RNA 3, Splice Region 3, Nonstop Mutation 1, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.431A>C p.Q144P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs786203071, CM023462, COSV52661000, COSV52675618, COSV52761562, COSV53080684; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.1865T>C p.M622T | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101036356; called by muse, mutect2, varscan2
- ABCC5 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV55593763, COSV99656238; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3480A>T p.Q1160H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as COSV99716429; called by muse, mutect2, varscan2
- ARHGAP18 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV100935983; called by muse, varscan2
- ARRDC3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs756630990, COSV99475117; called by mutect2, varscan2
- ASXL2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV99709958; called by muse, mutect2, varscan2
- ATP5F1B | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.054); catalogued as COSV100007918; called by muse, mutect2, varscan2
- ATP9B | c.2558A>G p.Q853R | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100302613; called by muse, mutect2
- ATRNL1 | c.1459T>A p.Y487N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100743670; called by muse, mutect2, varscan2
- ATRX | c.2243C>G p.S748C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100969829; called by muse, mutect2, varscan2
- BPIFB2 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs973371797, COSV50063301, COSV50070739; called by muse, mutect2, varscan2
- C12orf40 | c.407G>T p.S136I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.466); catalogued as COSV100209533; called by muse, mutect2, varscan2
- CACNA1H | c.3688C>A p.L1230M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100670413; called by mutect2, varscan2
- CAMK2A | c.1334G>T p.R445L (on ENST00000348628 / NM_171825.2; = p.R456L on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.341); catalogued as COSV100651921; called by muse, mutect2, varscan2
- CAPZA3 | c.252T>A p.F84L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.983); catalogued as COSV99855724; called by muse, mutect2, varscan2
- CARD18 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as COSV101596022; called by muse, mutect2, varscan2
- CCDC151 | c.964-1G>T p.X322_splice | Splice Site (SNP) | VAF 11/146 reads (8%) | catalogued as COSV100710431; called by muse, mutect2
- CENPE | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99476745; called by muse, mutect2, varscan2
- CGN | c.3610T>G p.*1204Eext*58 | Nonstop Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99641724; called by muse, mutect2, varscan2
- CHRM2 | c.684A>T p.Q228H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.722); catalogued as COSV100280529; called by muse, mutect2, varscan2
- CLCN5 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV100259711; called by muse, mutect2, varscan2
- CNR1 | c.556del p.R186Afs*54 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as COSV62986317, COSV62986418; called by mutect2, pindel, varscan2
- COL6A3 | c.4265G>T p.S1422I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99795862; called by muse, mutect2, varscan2
- COL9A3 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1159923081, COSV100673227; called by muse, mutect2
- CPSF6 | c.185A>T p.D62V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99878912; called by muse, mutect2
- CSF2 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99735567; called by muse, mutect2
- CSMD1 | c.4321T>G p.W1441G (on ENST00000520002; = p.W1440G on NM_033225.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100142050; called by muse, mutect2, varscan2
- CSMD3 | c.6299G>T p.W2100L (on ENST00000297405 / NM_001363185.1; = p.W1996L on NM_052900.3) | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52091146, COSV99821314; called by muse, mutect2, varscan2
- CST4 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV99462908; called by muse, mutect2, varscan2
- CTNNA3 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101044915; called by muse, mutect2, varscan2
- DCHS2 | n.3652C>A | Splice Region (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100250610; called by muse, varscan2
- DES | c.1280A>G p.N427S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs142712150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DKK2 | c.221A>T p.Q74L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99568014; called by muse, mutect2, varscan2
- DPAGT1 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 10/81 reads (12%) | catalogued as COSV100830663; called by muse, varscan2
- DSCAML1 | c.3551A>G p.K1184R (on ENST00000321322; = p.K1124R on NM_020693.4) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV100354205; called by muse, mutect2, varscan2
- DSTYK | c.940A>T p.S314C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.619); catalogued as COSV100904420; called by muse, mutect2, varscan2
- DYNC1H1 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs371431746; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECD | c.1375G>C p.A459P | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV100881315; called by muse, mutect2
- EPB41L4A | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV99812464; called by muse, mutect2, varscan2
- EPHB3 | c.1457A>G p.Y486C | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100382729; called by muse, mutect2, varscan2
- ESRRG | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63170527; called by muse, mutect2, varscan2
- FBXO30 | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99394920; called by muse, mutect2, varscan2
- FBXO41 | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99720775; called by mutect2, varscan2
- FER1L6 | c.1598T>A p.L533H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.321); catalogued as COSV101205275; called by muse, mutect2, varscan2
- FGD6 | c.2771A>G p.Y924C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs913892727, COSV100676311; called by muse, mutect2, varscan2
- FLG | c.4218C>A p.D1406E | Missense Mutation (SNP) | VAF 93/383 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV64236009; called by muse, mutect2, varscan2
- FLG2 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs1168649345, COSV101165548; called by muse, mutect2, varscan2
- FREM2 | c.5969G>T p.G1990V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99746158; called by muse, mutect2, varscan2
- FTO | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1178634936, COSV101149282; called by mutect2, varscan2
- GCM2 | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101069401; called by muse, mutect2, varscan2
- GDF2 | c.183C>G p.N61K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1255787900; called by muse, mutect2
- GHRHR | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV100396411; called by muse, mutect2, varscan2
- GLI2 | c.4339G>A p.G1447R (on ENST00000361492 / NM_001374353.1; = p.G1464R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs200274772, COSV100083743; called by muse, mutect2, varscan2
- GP2 | c.827C>A p.T276N (on ENST00000381362 / NM_001007240.3; = p.T273N on NM_001502.4) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV100221188; called by muse, mutect2, varscan2
- GPR149 | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1352248660, COSV101078037; called by muse, mutect2, varscan2
- GREM2 | c.193C>A p.R65S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100547238, COSV58958209; called by mutect2, varscan2
- GRIK2 | c.1808A>T p.E603V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100021975; called by muse, mutect2, varscan2
- GRIN2B | c.4373A>G p.N1458S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as rs577649736, COSV101662863; called by muse, mutect2, varscan2
- HENMT1 | c.673C>A p.Q225K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100898635; called by muse, mutect2, varscan2
- HERC5 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52043965, COSV99987283; called by muse, mutect2
- HIP1 | c.2866G>T p.G956C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as rs782738185, COSV100416743, COSV61187347; called by muse, mutect2, varscan2
- IDE | c.842A>T p.K281I | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99793705; called by muse, mutect2
- IFIT1B | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100879025; called by muse, mutect2, varscan2
- IFNA2 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs113974638, COSV101206962; called by muse, mutect2, varscan2
- IFNA2 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV101206964, COSV66505959; called by muse, mutect2, varscan2
- IGHMBP2 | c.2719A>G p.T907A | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.025); catalogued as COSV99661669; called by muse, mutect2
- IGHV5-51 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1555541625; called by muse, mutect2, varscan2
- IL17B | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99199151; called by muse, mutect2
- IL22 | c.399T>C p.H133= | Splice Region (SNP) | VAF 14/61 reads (23%) | catalogued as rs773093685, COSV100048739; called by muse, mutect2, varscan2
- INSRR | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs754589437, COSV63876113; called by muse, mutect2, varscan2
- IQUB | c.278A>C p.Q93P | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100226641; called by muse, mutect2
- IRF8 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV51900891, COSV99235948; called by muse, mutect2
- ITGA8 | c.1892T>C p.V631A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV100958663; called by muse, mutect2, varscan2
- KCND2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV100472855, COSV58594547; called by muse, mutect2, varscan2
- KCNQ2 | c.2423C>A p.S808Y (on ENST00000359125 / NM_172107.4; = p.S780Y on NM_004518.6) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60545776; called by muse, mutect2, varscan2
- KHDC4 | c.770G>C p.C257S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.152); catalogued as COSV100850751; called by mutect2, varscan2
- KIF6 | c.2384T>A p.I795N | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99756575; called by muse, mutect2
- LGALS13 | c.55T>A p.C19S | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as COSV99694852; called by muse, mutect2, varscan2
- LILRB4 | c.1251C>G p.H417Q (on ENST00000391733 / NM_001278428.3; = p.H416Q on NM_001278426.3) | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99553407; called by muse, mutect2
- LPP | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100446102; called by muse, mutect2
- LRIG3 | c.2494C>T p.H832Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756683559, COSV100292359, COSV57870673; called by muse, mutect2, varscan2
- LRP1B | c.3832A>T p.R1278* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV101250201; called by muse, mutect2
- LRTM2 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV99764915; called by muse, mutect2, varscan2
- MAGEB6 | c.1043G>C p.C348S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100983636; called by muse, mutect2, varscan2
- MCUR1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100848916; called by muse, mutect2, varscan2
- MEFV | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV54823724, COSV99560128; called by muse, mutect2, varscan2
- MEGF10 | c.1131-2A>T p.X377_splice | Splice Site (SNP) | VAF 10/83 reads (12%) | catalogued as COSV99174665; called by muse, mutect2, varscan2
- MID2 | c.1074-1G>C p.X358_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | catalogued as COSV53312306, COSV99463782; called by muse, mutect2, varscan2
- MLKL | c.244A>T p.R82* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100087156; called by muse, mutect2, varscan2
- MPHOSPH10 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99730908; called by muse, mutect2
- MTOR | c.4346G>C p.W1449S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100815627; called by muse, mutect2
- MYF5 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 15/121 reads (12%) | catalogued as COSV57357227, COSV99953074; called by muse, mutect2, varscan2
- MYH4 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99700152; called by muse, mutect2, varscan2
- NAV2 | c.2214T>C p.T738= (on ENST00000396087 / NM_001244963.2; = p.T715= on NM_145117.5) | Splice Region (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100584442; called by muse, mutect2, varscan2
- NEDD4 | c.3196T>C p.Y1066H (on ENST00000508342 / NM_001284338.1; = p.Y647H on NM_006154.4) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100163165; called by muse, mutect2, varscan2
- NIPA1 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507679; called by muse, mutect2, varscan2
- NISCH | c.105C>G p.I35M | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99234581; called by muse, mutect2, varscan2
- NOP9 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99852118; called by muse, mutect2, varscan2
- NOX4 | c.1075-1G>T p.X359_splice | Splice Site (SNP) | VAF 16/108 reads (15%) | catalogued as COSV99629248; called by muse, mutect2, varscan2
- NUP210L | c.2001G>A p.W667* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99666946; called by muse, mutect2, varscan2
- OR13C5 | c.91A>C p.I31L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101052991; called by muse, mutect2, varscan2
- OR2T12 | c.906G>C p.W302C | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100527473; called by muse, mutect2, varscan2
- OR2T2 | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV61617485, COSV61619107; called by muse, mutect2, varscan2
- OR4C11 | c.456A>G p.I152M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV100155101; called by muse, mutect2, varscan2
- OR4C12 | c.646T>C p.Y216H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as COSV100078174; called by muse, mutect2
- OR4C15 | c.938G>T p.R313L (on ENST00000314644; = p.R259L on NM_001001920.2) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs149965163, COSV58952933, COSV58954574; called by muse, mutect2
- OR4C46 | c.63G>T p.M21I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs372066510; called by muse, mutect2
- OR4C6 | c.461C>G p.A154G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.162); catalogued as COSV100051322; called by muse, mutect2, varscan2
- OR52B4 | c.912G>T p.Q304H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101281565, COSV68768991; called by muse, mutect2, varscan2
- OR52E4 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV100389106; called by muse, mutect2, varscan2
- OR5D18 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100450450, COSV100450929; called by muse, mutect2, varscan2
- OSTC | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.976); catalogued as COSV100843145; called by mutect2, varscan2
- PABPC5 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV57040884; called by muse, mutect2, varscan2
- PCDHA3 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.098); catalogued as COSV63544112; called by muse, mutect2, varscan2
- PCDHGA8 | c.1930G>T p.V644L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as COSV99528626; called by muse, mutect2, varscan2
- PCDHGB4 | c.1939G>A p.G647S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV99528624; called by muse, mutect2, varscan2
- PCDHGB7 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV99528629; called by muse, mutect2, varscan2
- PDGFRA | c.198C>A p.S66R | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV99955219; called by muse, mutect2, varscan2
- PGAP1 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100697944; called by muse, mutect2, varscan2
- PHACTR3 | c.1191A>T p.K397N | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100732139; called by muse, mutect2, varscan2
- PHF3 | c.5627C>T p.S1876L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV100012761; called by muse, mutect2, varscan2
- PKP2 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV99297089; called by muse, mutect2, varscan2
- PMFBP1 | c.2113C>T p.Q705* (on ENST00000537465; = p.Q700* on NM_031293.3) | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV99399923; called by muse, mutect2, varscan2
- POLE | c.4724A>G p.Y1575C | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1008362127, COSV100265042; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLQ | c.7202A>G p.Q2401R | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99951394; called by muse, mutect2, varscan2
- POLR2B | c.3184C>T p.R1062C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100107734; called by muse, mutect2
- PPEF2 | c.784-1G>T p.X262_splice | Splice Site (SNP) | VAF 5/56 reads (9%) | catalogued as COSV54423850, COSV99714011; called by muse, mutect2
- PRDM12 | c.414+2T>C p.X138_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV99446003; called by muse, mutect2, varscan2
- RANBP17 | c.797A>G p.N266S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs931695791, COSV101205972; called by muse, mutect2
- RASGRP3 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.897); catalogued as COSV101274649; called by muse, mutect2, varscan2
- REG3G | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); catalogued as COSV55451896; called by muse, mutect2, varscan2
- RESF1 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV100439999; called by muse, mutect2, varscan2
- RIMS1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757314703, COSV53469571; called by mutect2, varscan2
- RNASE1 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100564457; called by muse, mutect2
- ROBO4 | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV100127207, COSV60623411; called by muse, mutect2, varscan2
- RTP1 | c.172A>T p.K58* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100398631; called by muse, mutect2
- RYR2 | c.12328C>G p.P4110A | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100767215; called by muse, mutect2, varscan2
- SCN3B | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54801396; called by muse, mutect2, varscan2
- SCRIB | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1225345068, COSV100252270; called by muse, mutect2, varscan2
- SFTPA1 | c.338A>T p.D113V | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV100956865; called by muse, mutect2, varscan2
- SIK2 | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100515885; called by mutect2, varscan2
- SLC16A2 | c.856A>G p.S286G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as rs776291109, COSV99330281; called by muse, mutect2, varscan2
- SLC39A12 | c.1330C>A p.H444N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV101069786; called by muse, mutect2, varscan2
- SLC4A8 | c.1520G>C p.R507P | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as COSV100176327, COSV60659243; called by muse, mutect2, varscan2
- SON | c.1681C>G p.P561A | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.254); catalogued as COSV51654523, COSV99276465; called by muse, mutect2, varscan2
- SPATA6 | c.842G>T p.R281I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as COSV100892997; called by muse, mutect2, varscan2
- STEAP2 | c.169del p.V57Sfs*2 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | catalogued as COSV55292826; called by pindel, varscan2
- SUPT6H | c.3527A>T p.H1176L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV100111990; called by muse, mutect2, varscan2
- SZT2 | c.3753A>T p.E1251D (on ENST00000634258 / NM_001365999.1; = p.E1194D on NM_015284.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.99); catalogued as COSV100986833; called by muse, mutect2
- TAF1L | c.2428G>C p.V810L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99643966; called by muse, mutect2, varscan2
- TAF9 | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99472563; called by muse, mutect2, varscan2
- TBC1D32 | c.3524G>T p.C1175F | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99249179; called by muse, mutect2, varscan2
- TCHHL1 | c.916C>G p.L306V | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV100916490; called by muse, mutect2, varscan2
- TEX15 | c.8102C>T p.A2701V (on ENST00000256246; = p.A3084V on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746179351, COSV99820580; called by muse, mutect2, varscan2
- TIGD3 | c.1298A>G p.D433G | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV99361273; called by muse, mutect2, varscan2
- TMCC1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100261081, COSV100261156; called by muse, mutect2
- TMEM130 | c.718+1G>T p.X240_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100228497; called by muse, mutect2, varscan2
- TRAK2 | c.2644G>T p.G882C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100216560; called by muse, mutect2, varscan2
- TRHDE | c.2034G>T p.W678C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99668557; called by muse, mutect2, varscan2
- TRIM10 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758199472, COSV64998359; called by muse, mutect2, varscan2
- TTC6 | c.503T>A p.L168H (on ENST00000267368; = p.L1534H on NM_001310135.3) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV99941433; called by mutect2, varscan2
- UBE3D | c.367A>G p.K123E | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99387898; called by muse, mutect2
- UBIAD1 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1429309881, COSV100954776; called by muse, varscan2
- UGT2B10 | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607759; called by muse, mutect2, varscan2
- UHMK1 | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56419899; called by muse, mutect2, varscan2
- UNC80 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV55892339, COSV99778114; called by muse, mutect2
- USH2A | c.5662C>G p.L1888V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100240118, COSV56431513, COSV56452795; called by muse, mutect2, varscan2
- VNN3 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as rs1217753053, COSV99257920; called by muse, mutect2, varscan2
- VSIG10 | c.817G>T p.G273W | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100821231, COSV63653177; called by muse, mutect2, varscan2
- WDR45B | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as COSV101124380; called by muse, mutect2, varscan2
- WNT3 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56644840, COSV99843000; called by muse, mutect2
- WNT7A | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99540751; called by muse, mutect2, varscan2
- ZBTB20 | c.790G>T p.G264C (on ENST00000474710 / NM_001164342.2; = p.G191C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100612444; called by muse, varscan2
- ZNF280B | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as COSV100840151; called by muse, mutect2, varscan2
- ZNF354A | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.534); catalogued as COSV100234272; called by muse, mutect2, varscan2
- ZNF419 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99691714; called by muse, mutect2
- ZNF521 | c.1925A>G p.K642R | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.364); catalogued as COSV100831300, COSV64123106; called by muse, mutect2, varscan2
- ZNF780B | c.1915A>G p.K639E | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs762190622, COSV99665099; called by muse, mutect2, varscan2
- ZNF804A | c.3470C>A p.P1157H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56435888, COSV56452072; called by muse, mutect2
- CTTNBP2 | c.322del p.L108Sfs*65 | Frame Shift Del (DEL) | VAF 19/146 reads (13%) | called by mutect2, pindel, varscan2
- ENPP1 | c.2664del p.I889Sfs*24 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- FOXJ3 | c.1421A>G p.N474S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- HK3 | c.2600A>G p.D867G | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGHG1 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- KLF15 | c.528del p.P177Hfs*52 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by pindel, varscan2
- LPP | c.302del p.V101Dfs*24 | Frame Shift Del (DEL) | VAF 21/166 reads (13%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MYH7B | c.1271-12_1271-1delinsA p.X424_splice | Splice Site (DEL) | VAF 12/82 reads (15%) | called by pindel, varscan2*
- TBCK | c.1961del p.F654Sfs*7 (on ENST00000273980 / NM_001163436.4; = p.F591Sfs*7 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- TRAV38-1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRBV6-1 | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- UIMC1 | c.547dup p.W183Lfs*5 | Frame Shift Ins (INS) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- ZNF486 | c.965_970del p.Y322_T323del | In Frame Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ZNF804B | c.3233del p.P1078Rfs*8 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- ADAM29 | c.165C>A p.I55= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100821864, COSV63663246; called by muse, mutect2, varscan2
- ADAMTS16 | c.2211G>T p.V737= | Silent (SNP) | VAF 27/174 reads (16%) | catalogued as COSV99939590; called by muse, mutect2, varscan2
- ANKFN1 | c.501C>T p.L167= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100592974; called by muse, mutect2
- ASXL3 | c.5700G>C p.L1900= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV99322861; called by muse, mutect2
- CCDC63 | c.459G>A p.Q153= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as COSV100370119; called by muse, mutect2, varscan2
- CD28 | c.555G>A p.R185= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs1209365880, COSV100142206; called by muse, mutect2, varscan2
- CDH10 | c.2205C>A p.T735= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV52586944; called by muse, mutect2, varscan2
- CELSR2 | c.4926C>T p.L1642= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV54776423, COSV99602826; called by muse, mutect2, varscan2
- CTNNA2 | c.2817G>T p.S939= (on ENST00000402739 / NM_001282597.3; = p.S891= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs529719349, COSV100559150, COSV58143856; called by muse, mutect2
- CTNNA3 | c.219A>G p.G73= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV100373165; called by muse, mutect2
- DHRS2 | c.144C>T p.I48= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs576958094, COSV51634380; called by muse, mutect2, varscan2
- DNAH9 | c.729G>A p.G243= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99303218; called by muse, mutect2
- ETV1 | c.654A>G p.P218= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99622261; called by muse, mutect2, varscan2
- F2RL2 | c.390A>G p.V130= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99166629; called by muse, mutect2, varscan2
- FAM135B | c.3663C>T p.N1221= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs768830757, COSV99417443; called by muse, mutect2, varscan2
- FAM13B | c.2739A>G p.K913= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99220856; called by muse, mutect2, varscan2
- FCRL4 | c.750C>T p.T250= | Silent (SNP) | VAF 77/330 reads (23%) | catalogued as rs775384031, COSV99619138; called by muse, mutect2, varscan2
- FREM2 | c.5970A>T p.G1990= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99746161; called by muse, mutect2, varscan2
- HAVCR1 | c.414T>A p.V138= | Silent (SNP) | VAF 44/377 reads (12%) | catalogued as COSV100207815; called by muse, mutect2, varscan2
- HECTD1 | c.5157C>A p.R1719= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV101237291; called by muse, mutect2
- HOXC9 | c.675G>C p.V225= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100327350; called by muse, mutect2, varscan2
- JPH3 | c.972C>T p.G324= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99412604; called by muse, mutect2, varscan2
- KCNK10 | c.1443G>T p.L481= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100067033; called by muse, mutect2, varscan2
- KY | c.1284G>C p.V428= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV101414931; called by muse, mutect2
- LEO1 | c.225T>C p.S75= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV100166363; called by muse, mutect2, varscan2
- MCF2 | c.652C>T p.L218= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs756706338, COSV100644339; called by mutect2, varscan2
- MUC17 | c.7644T>A p.T2548= | Silent (SNP) | VAF 34/288 reads (12%) | catalogued as rs746257896, COSV100071164; called by muse, mutect2, varscan2
- MYH6 | c.3801G>A p.E1267= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1344804774, COSV62452463; called by muse, mutect2, varscan2
- NDUFS1 | c.1197T>A p.V399= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99260200; called by muse, mutect2, varscan2
- NR1H2 | c.951G>A p.R317= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- NRG3 | c.570T>G p.P190= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100930355; called by muse, mutect2, varscan2
- NTN4 | c.1359G>C p.G453= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs755907823, COSV100643631; called by muse, mutect2, varscan2
- NUDT16L1 | c.582A>C p.A194= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99273662; called by muse, mutect2
- OR10Q1 | c.87T>C p.V29= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100372110; called by muse, mutect2, varscan2
- OR2M2 | c.258G>T p.L86= | Silent (SNP) | VAF 36/382 reads (9%) | catalogued as COSV100677141; called by muse, mutect2
- OR4N2 | c.459T>C p.F153= | Silent (SNP) | VAF 21/183 reads (11%) | catalogued as COSV60051273; called by muse, mutect2, varscan2
- OR8U1 | c.672C>A p.A224= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV100163687, COSV56418387; called by muse, mutect2, varscan2
- PPP2R2C | c.927G>A p.L309= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100160128; called by muse, mutect2, varscan2
- PTPRN | c.1977C>A p.S659= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV99833578; called by muse, mutect2
- PYCARD | c.576G>A p.L192= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99910862; called by muse, mutect2
- SERPINB10 | c.147C>A p.T49= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV99448529; called by muse, mutect2
- SLC39A10 | c.2091A>G p.T697= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs778835420, COSV100660439; called by muse, mutect2, varscan2
- SYNPR | c.756C>A p.G252= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99887412; called by muse, mutect2, varscan2
- TCERG1 | c.2040G>T p.T680= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV57039675, COSV99694289; called by muse, mutect2, varscan2
- TTC14 | c.531G>T p.G177= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV56009203, COSV99931751; called by muse, mutect2, varscan2
- USH2A | c.11796G>A p.L3932= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100227778; called by muse, mutect2
- WDR62 | c.1791C>T p.I597= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs895065710, COSV99543035, COSV99543551; called by muse, mutect2, varscan2
- ZNF160 | c.405G>A p.Q135= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV100762200; called by muse, mutect2
- ZNF44 | c.846C>T p.F282= (on ENST00000356109 / NM_001164276.2; = p.F234= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV100633430; called by muse, mutect2, varscan2
- ZNF536 | c.3084G>T p.A1028= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV62834823; called by muse, mutect2, varscan2
- AL109984.1 | chr20:52098492 C>A | 3'Flank (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100800743; called by muse, mutect2, varscan2
- DCHS2 | n.7527T>A | RNA (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100600891; called by muse, mutect2, varscan2
- EEF1A1P22 | n.107A>G | RNA (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- MIR18A | n.55A>G | RNA (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- PAQR6 | c.*251C>A | 3'UTR (SNP) | VAF 18/236 reads (8%) | catalogued as COSV99430651; called by muse, mutect2
